Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7390, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7390-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) TONGUE, RIGHT, BIOPSY: MODERATELY-DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA.
- 2) MOUTH, PALATAL MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 3) MOUTH, FLOOR, MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 4) BUCCAL MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 5) LYMPH NODES, RIGHT NECK LEVEL 2 AND 3, EXCISION: 13 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/13).
- 6) LYMPH NODES, RIGHT NECK LEVEL 1B, EXCISION: 2 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/2).
- 7) TEETH: FOR MACROSCOPIC EVALUATION ONLY [SEE GROSS DESCRIPTION].
- 8) ORAL CAVITY, "RIGHT TONGUE CANCER LEVEL 1B", RESECTION: MODERATELY-DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA INVOLVING RIGHT TONGUE AND MOUTH FLOOR, WITH INVASION INTO THE DEEP TONGUE MUSCLES AND NO INVASION INTO MANDIBLE, 5.0 CM IN GREATEST DIMENSION, ALL MARGINS NEGATIVE [CLOSEST MARGIN (POSTERIOR) 0.6 CM].
- 9) LYMPH NODE, PREHYOID, EXCISION: 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

COMMENT: These findings correspond with AJCC pathologic Stage IVA (pT4a, pNo).

Upper Aerodigestive Tract and Minor Salivary Glands Carcinoma

Summary of Findings:

Specimen Type: En-bloc resection: right tongue, mandible, floor of mouth and other associated tissues

Tumor Site: Right lateral tongue

Tumor Size: 5 cm x 4.8 cm

Histologic Type: squamous cell carcinoma

Histologic Grade: Moderately differentiated

[page 2 of 5]
Pathologic Staging (pTMN) IVa

Primary tumor (pT): pT4a

Regional Lymph Nodes (pN): pNo

Number examined: 16

Numbered involved: 0

Extracapsular extension: N/A

Perineural invasion: (Select one) ☒ Yes ☐ No ☐ Not evaluable

Bony/Cartilage Invasion: (Select one) ☐ Yes ☒ X ☐ No ☐ Not evaluable

HPV testing ordered: Yes (performed on oral cavity and oropharyngeal squamous cell carcinomas)

**Electronically Signed Out by

CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) Right tongue, 2) palatal margin, 3) floor of mouth margin, 4) buccal margin, 5) right neck level 2&3, 6) right neck level 1B, 7) teeth (for gross diagnosis only), 8) right tongue cancer level 1B, 9) prehyoid lymph node

GROSS DESCRIPTION:

1) SOURCE: Right Tongue

Received fresh, labeled "right tongue" are portions of pink-tan mucosal tissue measuring in aggregate 1.8 x 0.5 x 0.5 cm. The specimen is submitted for frozen sectioning. The remainder of the specimen is submitted entirely. Summary of sections: 1AFSC, M/1.

2) SOURCE: Palatal Margin

Received fresh for frozen section diagnosis in a container labeled "palatal margin" is 1 fragment of soft tissue that measures 4.3 x 0.5 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis. Summary of sections: 2AFSC, frozen section control, 2/1.

3) SOURCE: Floor of Mouth Margin

Received fresh for frozen section diagnosis in a container labeled "floor of mouth" is 1 fragment of soft tissue that measures 3.5 x 0.2 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis. Summary of sections: 3AFSC, frozen section control, 2/1.

[page 3 of 5]
4) SOURCE: Buccal Margin

Received fresh for frozen section diagnosis in a container labeled "buccal margin" is 1 fragment of soft tissue that measures 8.3 x 0.2 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis.
Summary of sections: 4AFSC, frozen section control, 3/1.

5) SOURCE: Right Neck Level 2 and 3

Received fresh in a container labeled "right neck level 2, 3" are multiple fragments of fibrofatty tissue that in aggregate measure 9.0 x 6.0 x 2.3 cm. The specimen is searched for lymph nodes and 12 possible lymph nodes are identified. Two possible lymph nodes are submitted entirely in cassette 5A. Two possible lymph nodes are submitted entirely in cassette 5B. One possible lymph node is bisected and submitted in cassette 5C. One possible lymph node is bisected and submitted in cassette 5D. One possible lymph node is bisected and submitted in cassette 5E. One possible lymph node is bisected and half is submitted in cassette 5F and half is submitted in cassette 5G. One possible lymph node is bisected and half is submitted in cassette 5A and half is submitted in cassette 5H. One possible lymph node is bisected and submitted in cassette 5J. One possible lymph node is bisected and submitted in cassette 5K and one possible lymph node is bisected and submitted in cassette 5L.
Summary of sections: 5A-5E, 2/1 each; 5F-5I, 1/1 each; 5J-5L, 2/1 each.

6) SOURCE: Right Neck Level 1B

Received fresh in a container labeled "right neck level 1B," is one fragment of fibrofatty tissue that measure 6.3 cm x 3.5 x 0.8 cm. The specimen is searched for lymph nodes and 2 possible lymph nodes are identified. One possible lymph node is bisected and submitted in cassette 6A. A second possible lymph node is bisected and submitted in cassette 6B.
Summary of sections: 6A, 2/1 each.

7) SOURCE: Teeth

Received fresh in a container labeled "teeth for gross only" are 6 incisors that in aggregate measure 5.0 x 4.0 x 0.7 cm. There do not grossly appear to be any cavities or fillings. A photograph is taken and the specimen is submitted for gross only pathologic diagnosis.

8) SOURCE: Right Tongue Cancer Level 1B

Received in formalin in a container labeled "right tongue cancer level 1B" is a portion of right tongue with attached mandible and soft tissue that measures 11 x 10 x 7.5 cm. The tongue measures 10 cm from anterior to posterior, 4.5 cm from right to left, and 3.3 cm from superior to inferior. The attached mandible measures 5.6 cm from anterior to posterior, 0.6 cm from right to left, and 3.2 cm from superior to inferior. The specimen is inked as follows: anterior orange, lateral red, medial yellow, posterior black and inferior green. There is an ulcerated tumor at the right floor of the mouth that measures 5.0 x 4.8 cm. A portion of the tumor is given to research is placed in glutaraldehyde and also submitted in -80 degree. The

[page 4 of 5]
medial soft tissue margin closest to the tumor is submitted in cassette 8A and 8B. This margin appears grossly to be 1.8 cm away from the tumor. The inferior margin to tumor is submitted in cassette 8C. This margin appears to be 0.3 cm from tumor. There is a submandibular gland inferior to the specimen that measures 4.3 x 2.5 x 2.3 cm. The tumor does not appear grossly to extend into this gland. Representative sections of the gland are submitted in cassette 8D and 8E. Posterior soft tissue margins to tumor is submitted in cassette 8F. This margin grossly appears to be 0.4 cm away from tumor. The anterior tongue margin is submitted in cassette 8G. The anterior soft tissue margin is submitted in cassette 8H and this margin appears grossly to be 1.5 cm away from tumor. Another posterior soft tissue margin that appears grossly to the 0.4 cm away from tumor is submitted in cassette 8I. A representative section of superior tongue tumor is submitted in cassette 8J. The superior portion of the tongue appears to be grossly involved by tumor. The lateral margin is composed of the mandible. The anterior mandibular margin is submitted in cassette 8K. The posterior mandible margin is submitted in cassette 8L. The lateral mandibular margin to tumor is submitted in cassette 8M. Grossly, the mandible does not appear to be involved by tumor. Representative sections of tumor are submitted in cassette 8N-8R.

Summary of sections: 8A-8Q, 1/1 each; 8R, 2/1; cassettes 8K, 8L and 8M are submitted following decalcification.

9) SOURCE: Prehyoid Lymph Node

Received fresh in a container labeled "prehyoid lymph node" is one fragment of fibrofatty tissue that measures 1.0 x 1.0 cm x 0.4 cm. The fragment is entirely submitted in cassette 9A.

Summary of sections: 9A, 1/1.

Dictated by [REDACTED]

Source 1 only

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Right Tongue

FROZEN SECTION DIAGNOSIS: SQUAMOUS CELL CARCINOMA. [REDACTED]

2) SOURCE: Palatal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

3) SOURCE: Floor of Mouth Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

4) SOURCE: Buccal Margin

[REDACTED]

[page 5 of 5]
FROZEN SECTION DIAGNOSIS: [REDACTED]

Electronically signed by: [REDACTED] Attending Pathologist

The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:
3xDECALCIFICATION OF BLOCK

In some tests, analyte specific reagents (ASRs) are used. In the case of an ASR, this test was developed and its performance characteristics determined by this laboratory. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA [REDACTED]) as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file b8d906a3-0866-4b47-ae14-22067d85023d (TCGA-CR-7390.3DFBAB9D-ED2C-49DD-A7D5-B67FA8FB921B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).